BEATAML1.0 case 2504 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/84f425c2-2c61-4e68-b3e0-9ccab2a3dcc3

Demographics
Sex at birth: male.

Diagnoses (1)
1. Acute promyelocytic leukaemia, PML-RAR-alpha: ICD-O-3 morphology code: 9866/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.9 years (20,404 days); Progression or recurrence: no; ELN risk classification: Favorable.

Biospecimens (2 samples)
- Sample BA2150D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA2191D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
